Somatic mutation profile of tumor specimen 0DQZ4D from CCDI case PBCFNW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.0 years (355 days).
Specimen 0DQZ4D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9138fbf1-a20b-43c6-955d-801e0d4c0f25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQZ3G (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78688fbd-a554-476b-a65f-c395d12257df

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NECAP2 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 32/257 reads (12%) | catalogued as rs767888125, COSV100452374; called by muse, mutect2, varscan2
- PLCH2 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 77/255 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760532972, COSV53940727; called by muse, mutect2, varscan2
- TMEM42 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs559908499; called by mutect2, varscan2
- ZFHX3 | c.10337G>A p.S3446N | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1313741097; called by muse, mutect2
